Somatic mutation profile of tumor specimen 0DVU3R from CCDI case PBCMER, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.0 years (381 days).
Specimen 0DVU3R: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1664a660-201e-482c-b8df-68d07cd4dccc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVU3T (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1313491b-22ed-4777-b5e4-74759e2b412c

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Intron 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.4036T>C p.S1346P | Missense Mutation (SNP) | VAF 48/381 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.847); catalogued as COSV67129779; called by muse, mutect2, varscan2
- AKAP10 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 12/436 reads (3%) | catalogued as COSV99855247; called by muse, mutect2
- CADPS2 | c.2881C>T p.P961S | Missense Mutation (SNP) | VAF 17/650 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV57347495; called by muse, mutect2
- MINDY1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 14/359 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV56500809; called by muse, mutect2
- OR9K2 | c.129G>T p.R43S (on ENST00000305377; = p.R21S on NM_001005243.1) | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.371); catalogued as COSV59531715; called by muse, mutect2, varscan2
- PPFIBP1 | c.1953G>T p.Q651H (on ENST00000318304 / NM_177444.3; = p.Q645H on NM_003622.4) | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57297678; called by muse, mutect2
- SLCO1B1 | c.1355G>C p.R452T | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs767997802; called by muse, mutect2, varscan2
- ZNF777 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 14/548 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1472517054; called by muse, mutect2
- AKAP10 | c.1463A>T p.E488V | Missense Mutation (SNP) | VAF 12/426 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA2012 | c.2417C>A p.P806H | Missense Mutation (SNP) | VAF 101/477 reads (21%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- NRDE2 | c.2896A>T p.T966S | Missense Mutation (SNP) | VAF 8/286 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2
- ZNF277 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 26/884 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABLIM2 | c.1743G>A p.E581= (on ENST00000341937 / NM_001130084.2; = p.E491= on NM_032432.5) | Silent (SNP) | VAF 21/420 reads (5%) | called by muse, mutect2
- ENAH | c.870C>T p.G290= | Silent (SNP) | VAF 16/394 reads (4%) | called by muse, mutect2
- MFSD13A | c.60C>A p.G20= | Silent (SNP) | VAF 74/149 reads (50%) | called by muse, varscan2
- NFATC3 | c.1146T>G p.P382= | Silent (SNP) | VAF 55/283 reads (19%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.62-85C>G | Intron (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- CCAR1 | c.2880+63A>G | Intron (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- DMD | c.2292+84T>A | Intron (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- STAG3 | c.1574-83A>G | Intron (SNP) | VAF 8/70 reads (11%) | catalogued as COSV57935957; called by muse, mutect2, varscan2
